Gene-level copy-number profile of tumor specimen C3L-09614-02 from CPTAC case C3L-09614, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.1 years (20,109 days).
Specimen C3L-09614-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69f2ca94-26b4-401f-b9b3-cbfe9d0e4557.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09614-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/7588a8fc-7bdf-4778-aa66-6d65e8a4d2f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 8,576; copy number 2: 41,639; copy number 3: 8,649; copy number 4: 9.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,841,357, 4 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–2): PRAMEF2.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:130,611,440–130,718,831, 6 genes: POTEJ, RNU6-848P, CYP4F30P, AC140481.3, FAR2P3, KLF2P3.
- chr6:99,918,519–99,994,247, 1 gene (within-gene range 0–1): MCHR2.
- chr10:47,689,707–48,119,455, 12 genes: SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
